Somatic mutation profile of tumor specimen TCGA-G8-6324-01A (aliquot TCGA-G8-6324-01A-11D-2210-10) from TCGA case TCGA-G8-6324, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Intra-abdominal lymph nodes; Age at diagnosis: 43.1 years (15,750 days).
Specimen TCGA-G8-6324-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a517e50-1d53-49ca-8c0e-a568eeb6e051.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G8-6324-10A (Blood Derived Normal), aliquot TCGA-G8-6324-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b709906c-599d-4142-a945-9f19f90e924f

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 3, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 64/198 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL21A1 | c.2343T>G p.D781E | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.444); catalogued as rs545860371; called by muse, mutect2, varscan2
- DDX3X | c.1036G>C p.D346H (on ENST00000399959; = p.D347H on NM_001356.5) | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863429; called by muse, mutect2, varscan2
- DPP8 | c.478C>T p.R160C (on ENST00000341861 / NM_001320875.2; = p.R144C on NM_017743.6) | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770610586, COSV100202088; called by muse, mutect2, varscan2
- IRF4 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV66704365; called by muse, mutect2, varscan2
- NOTCH1 | c.7541_7542del p.P2514Rfs*4 | Frame Shift Del (DEL) | VAF 53/105 reads (50%) | catalogued as rs763016003, COSV53024776; ClinVar: uncertain significance; called by mutect2, varscan2
- RFX7 | c.2054G>A p.W685* (on ENST00000559447 / NM_001368074.1; = p.W782* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | catalogued as COSV57960250; called by muse, mutect2, varscan2
- SSBP3 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs760137994; called by muse, mutect2, varscan2
- STYXL2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs754706168, COSV54803783; called by muse, mutect2, varscan2
- ARID1A | c.3207_3209del p.K1069del | In Frame Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- ARMCX5-GPRASP2 | c.1448A>T p.N483I | Missense Mutation (SNP) | VAF 60/402 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- BAHCC1 | c.3709C>T p.R1237* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- CDK5R1 | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- DNAH5 | c.10697T>A p.M3566K | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- DOCK7 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FOXA2 | c.728T>C p.F243S (on ENST00000377115 / NM_153675.3; = p.F249S on NM_021784.5) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNX18 | c.954G>C p.W318C | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSBP2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF251 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.825); called by muse, mutect2
- AMPD3 | c.2100C>T p.S700= (on ENST00000396553 / NM_001025389.2; = p.S709= on NM_000480.3) | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as rs375685508; called by muse, mutect2, varscan2
- BCAT1 | c.459A>G p.P153= | Silent (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- IGHM | c.399C>T p.I133= | Silent (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- PTPRT | c.540C>T p.D180= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs1246950792, COSV61987709; called by muse, mutect2, varscan2
